Somatic mutation profile of tumor specimen MP2PRT-PAVWUF-TMP1-A (aliquot MP2PRT-PAVWUF-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVWUF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,576 days).
Specimen MP2PRT-PAVWUF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e710ab48-37cc-44ab-a018-f6a1e375e82c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWUF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWUF-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f82b952-d562-4e59-8715-876ac2bf443d

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, 5'UTR 1, Nonsense Mutation 1, Intron 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSH1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs147130406; called by muse, mutect2
- MAST2 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 45/542 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as rs762076953, COSV100788001, COSV100788592; called by muse, mutect2
- PCDHB10 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 90/963 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.107); catalogued as rs1175200567; called by muse, mutect2
- PCDHB9 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 276/969 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs529686576; called by muse, mutect2, varscan2
- TYRP1 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | catalogued as rs758093517, COSV66357755; called by muse, mutect2, varscan2
- XBP1 | c.509G>C p.R170P | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV53274438; called by muse, varscan2
- ADAMTS9 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP9A | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 150/356 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.954C>A p.D318E | Missense Mutation (SNP) | VAF 153/195 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLF18 | c.2704G>A p.G902S | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR5D16 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 18/475 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPFIA2 | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLC18A3 | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 63/778 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- SORCS1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XBP1 | c.548dup p.Q184Pfs*203 | Frame Shift Ins (INS) | VAF 47/354 reads (13%) | called by pindel, varscan2
- YPEL2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2
- BAIAP3 | c.2643G>A p.S881= | Silent (SNP) | VAF 150/365 reads (41%) | catalogued as rs562258290, COSV50103899; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.819C>G p.S273= | Silent (SNP) | VAF 19/428 reads (4%) | catalogued as rs919554835; called by muse, mutect2
- AC024598.1 | c.1130-962C>A | Intron (SNP) | VAF 196/450 reads (44%) | called by muse, mutect2, varscan2
- TENT5A | c.-203G>T | 5'UTR (SNP) | VAF 57/509 reads (11%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451425 G>A | 5'Flank (SNP) | VAF 58/697 reads (8%) | catalogued as rs1452848842; called by muse, mutect2
